Somatic mutation profile of tumor specimen TCGA-OX-A56R-01A (aliquot TCGA-OX-A56R-01A-11D-A33T-08) from TCGA case TCGA-OX-A56R, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 68.9 years (25,178 days).
Specimen TCGA-OX-A56R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ade00a5e-8703-4acb-a7bc-467deaedff0e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OX-A56R-10A (Blood Derived Normal), aliquot TCGA-OX-A56R-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/01ca413a-63ae-4017-935c-a58195e73eea

The open-access MAF lists 40 somatic variants for this specimen: 33 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 28, Silent 7, Frame Shift Del 2, Frame Shift Ins 1, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 73/169 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs139236063, COSV51769031, COSV51808387; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 41/43 reads (95%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM981671, CM993670, COSV64293729, COSV64297280; called by muse, mutect2, varscan2
- ADAMTS9 | c.1343A>G p.N448S | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0.023); catalogued as rs1162386499, COSV99900070; called by muse, mutect2, varscan2
- AQP2 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT tolerated (0.55); PolyPhen benign (0.01); catalogued as COSV99550916; called by muse, mutect2, varscan2
- ARMH3 | c.1210G>T p.D404Y | Missense Mutation (SNP) | VAF 24/31 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100899019; called by muse, mutect2, varscan2
- ATP11A | c.2888G>A p.R963H | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.608); catalogued as rs778847637, COSV52121868; called by muse, mutect2, varscan2
- CIBAR1 | c.388_391del p.L130Kfs*47 | Frame Shift Del (DEL) | VAF 18/45 reads (40%) | catalogued as rs775881725; called by mutect2, pindel, varscan2
- DGKB | c.715G>A p.V239M | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.847); catalogued as rs566651894, COSV99342750; called by muse, mutect2, varscan2
- DGKQ | c.1793G>A p.G598E | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99298134; called by muse, mutect2, varscan2
- DYNC2H1 | c.4072C>T p.R1358C | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs771671546, COSV62092633; called by muse, mutect2, varscan2
- FNBP4 | c.1069G>C p.E357Q | Missense Mutation (SNP) | VAF 67/153 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as rs755260616, COSV99771927; called by muse, mutect2, varscan2
- GRM7 | c.527A>G p.Q176R | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100738146, COSV63149534; called by muse, mutect2, varscan2
- HOPX | c.17C>T p.A6V (on ENST00000317745; = p.A24V on NM_032495.6) | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs1484619983, COSV100497081; called by muse, mutect2
- IGHV3-15 | c.182G>A p.G61E | Missense Mutation (SNP) | VAF 48/55 reads (87%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.954); catalogued as rs1295014322; called by muse, mutect2, varscan2
- KDM6B | c.3296C>T p.P1099L | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.34); catalogued as rs1207390079, COSV99642157; called by muse, mutect2, varscan2
- MFHAS1 | c.3020G>A p.R1007K | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.97); catalogued as COSV52286556; called by muse, mutect2, varscan2
- NLRP4 | c.596C>T p.T199M | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as rs370421219; called by muse, mutect2, varscan2
- NPAS3 | c.290C>G p.T97R (on ENST00000356141 / NM_001164749.2; = p.T67R on NM_022123.3) | Missense Mutation (SNP) | VAF 61/68 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100389532; called by muse, mutect2, varscan2
- OR14C36 | c.315dup p.V106Cfs*14 | Frame Shift Ins (INS) | VAF 18/36 reads (50%) | catalogued as rs761899382; called by mutect2, varscan2
- OR51I2 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 64/154 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs746240729, COSV58298444; called by muse, mutect2, varscan2
- PLIN4 | c.2414A>C p.D805A (on ENST00000301286; = p.D820A on NM_001367868.2) | Missense Mutation (SNP) | VAF 54/220 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100013986; called by muse, mutect2, varscan2
- PRAME | c.660G>A p.M220I | Missense Mutation (SNP) | VAF 53/58 reads (91%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV101287217; called by muse, mutect2, varscan2
- PRB2 | c.842G>A p.G281E | Missense Mutation (SNP) | VAF 184/544 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.014); catalogued as COSV66984555; called by muse, varscan2
- REC8 | c.145G>C p.V49L | Missense Mutation (SNP) | VAF 39/42 reads (93%) | SIFT tolerated (0.11); PolyPhen benign (0.443); catalogued as COSV100269204; called by muse, mutect2, varscan2
- RMND5B | c.514G>C p.G172R | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs1379297709, COSV100523332; called by muse, mutect2, varscan2
- RRH | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100496212; called by muse, mutect2, varscan2
- SHANK2 | c.5278C>T p.R1760C | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV53594633; called by muse, mutect2, varscan2
- SOX9 | c.751G>A p.D251N | Missense Mutation (SNP) | VAF 94/210 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.326); catalogued as COSV55430094, COSV99818705; called by muse, mutect2, varscan2
- THSD7A | c.2654G>A p.C885Y | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101448864; called by muse, mutect2, varscan2
- UGT2B10 | c.1426C>T p.R476* | Nonsense Mutation (SNP) | VAF 78/182 reads (43%) | catalogued as rs754651977, COSV99608695; called by muse, mutect2, varscan2
- ZEB2 | c.19G>C p.A7P | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV100356707; called by muse, mutect2, varscan2
- QKI | c.521_523del p.E174del | In Frame Del (DEL) | VAF 38/48 reads (79%) | called by pindel, varscan2
- SGO1 | c.877_878del p.E293Rfs*6 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | called by pindel, varscan2
- IVL | c.345G>A p.R115= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV100908257, COSV64216594; called by muse, mutect2
- KMT2C | c.9915C>T p.P3305= | Silent (SNP) | VAF 24/85 reads (28%) | catalogued as COSV100075805; called by muse, mutect2, varscan2
- MYF5 | c.156C>T p.D52= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as COSV57356341; called by muse, mutect2, varscan2
- OR5H6 | c.63T>C p.N21= (on ENST00000642105; = p.N5= on NM_001005479.2) | Silent (SNP) | VAF 70/145 reads (48%) | catalogued as rs1289917535, COSV101051806; called by muse, mutect2
- PCDHA3 | c.2175G>A p.A725= | Silent (SNP) | VAF 77/192 reads (40%) | catalogued as COSV63540850, COSV63544256; called by muse, mutect2, varscan2
- PROX1 | c.1986C>T p.Y662= | Silent (SNP) | VAF 53/105 reads (50%) | catalogued as COSV99800092; called by muse, mutect2, varscan2
- PTGFRN | c.288G>A p.R96= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as rs999372120, COSV101277444; called by muse, mutect2, varscan2
